CPTAC case C3L-01154 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cda51538-afb7-4428-9530-81ce928f0f98

Demographics
Sex at birth: female; Race: white; Year of birth: 1965; Vital status: Dead; Days to death: 496 days (1.4 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 52.0 years (18,992 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 496 days (1.4 years); Progression or recurrence: no; Days to last follow up: 496 days (1.4 years).
   Pathology details: Greatest tumor dimension: 3.2 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Hormone Therapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 351 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 496 days (1.4 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 230 days; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 74 kg; Height: 165 cm; BMI: 27.18.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01154-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 100 mg; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01154-22: Section location: Right hemisphere parietal lobe, occipital and  temporal lobe, and splenium of corpus callosum; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-01154-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 120 mg; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01154-23: Section location: Right hemisphere parietal lobe, occipital and  temporal lobe, and splenium of corpus callosum; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-01154-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
